Gene-level copy-number profile of tumor specimen ALCH-AEPV-TTP1-A from ALCHEMIST case ALCH-AEPV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.6 years (22,484 days).
Specimen ALCH-AEPV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4d8cec7e-2bfb-4629-ae5b-5b41924a9e37.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEPV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/c5229767-f330-47dc-a7f1-e4b402668895

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 1,109; copy number 2: 54,807; copy number 3: 2,357; copy number 4: 75; copy number 5: 3; copy number 7: 1; copy number 9: 2; copy number 10: 1; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,049,203–2,050,070, 1 gene: AL391845.1.
- chr1:31,652,263–31,704,319, 1 gene (within-gene range 0–2): COL16A1.
- chr1:120,432,204–120,434,052, 1 gene: PFN1P2.
- chr3:75,415,070–75,435,110, 2 genes: ALG1L6P, FAM86DP.
- chr3:129,555,214–129,606,676, 2 genes: PLXND1, RN7SL752P.
- chr3:138,434,586–138,481,686, 1 gene: ESYT3.
- chr3:198,110,112–198,123,232, 3 genes: FRG2FP, TUBB8P8, AC073135.1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr10:49,734,641–49,773,299, 2 genes: OGDHL, MAPK6P6.
- chr11:1,919,703–1,938,706, 1 gene: TNNT3.
- chr12:132,200,436–132,201,287, 1 gene (within-gene range 0–2): AC138466.4.
- chr13:45,060,729–45,061,086, 1 gene (within-gene range 0–2): RN7SKP3.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–1): RNA5SP393.
- chr15:88,252,730–88,271,066, 1 gene (within-gene range 0–2): NTRK3-AS1.
- chr16:31,427,731–31,443,160, 3 genes: COX6A2, AC026471.5, ZNF843.
- chr19:17,207,138–17,219,829, 2 genes (within-gene range 0–2): AC020913.2, USE1.
- chr20:17,613,678–17,682,295, 1 gene: RRBP1.
- chr21:45,403,809–45,404,369, 1 gene: BX322562.1.
- chr22:24,181,487–24,189,106, 1 gene: SUSD2.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–2): CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:167,784–207,428, 3 genes, copy number 5 (within-gene range 2–5): BET1L, SCGB1C1, ODF3.
- chr11:1,947,278–1,984,522, 1 gene, copy number 10 (within-gene range 1–10): MRPL23.
- chr14:104,857,792–104,858,836, 1 gene, copy number 9: AL583810.1.
- chr21:44,133,610–44,210,114, 1 gene, copy number 19 (within-gene range 2–19): GATD3A.
- chr22:18,715,815–18,757,906, 2 genes, copy number 7–9: PPP1R26P4, FAM230E.

Autosomal genes at a single copy (total copy number 1): 981. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
